Surgical pathology report (de-identified scan), TCGA case TCGA-91-6836, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site ABS - IUPUI, specimen TCGA-91-6836-01A (Primary Tumor).

[page 1 of 3]
Final Pathologic Diagnosis:

- A. Lymph node, right level 10, excision:
One benign lymph node.
- B. Lymph node, right level 4, excision:
Three benign lymph nodes.
- C. Lymph node, right level 2, excision:
Three benign lymph nodes.
- D. Lymph node, level 7, excision:
One benign lymph node.
- E. Lung, right upper lobe, lobectomy [FSE]:
Adenocarcinoma.

Specimen: Lung, right upper lobe

Procedure: Lobectomy

Specimen laterality: Right

Tumor site: Upper lobe

Specimen integrity: Disrupted

Tumor size (greatest dimension): 4 cm

Tumor focality: Unifocal

Tumor histologic type: Adenocarcinoma, with extensive necrosis

Tumor grade: 2, moderately differentiated

Visceral pleura invasion: Not identified

Tumor extension: Not applicable

Margins:

Bronchial: Uninvolved by invasive carcinoma

Vascular: Uninvolved by invasive carcinoma

Treatment effect: Cannot be determined

Lymph-vascular invasion: Not identified

Pathologic staging (pTNM):

TNM Descriptors: None

Primary tumor: pT2

Regional lymph nodes: pN0 (including Parts A-B, F)

Number examined: 10

Number involved: 0

Distant metastasis: Cannot be assessed

Additional pathologic findings: Obstructive pneumonia

One benign lymph node.

Frozen section diagnosis confirmed.

- F. Lymph node, level 8, excision:
Fragments of benign anthracotic lymph node.

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Electronically Signed, [Redacted] (Pathologist)

Signing Location:

Intraoperative Consult Diagnosis:

[page 2 of 3]
FSE: Right upper lobe diagnosed mass:
Non-small cell carcinoma.
F/S TAT: 11 mins.

Gross Description:

Received are six specimen containers all labeled with the patient's name,
" ."

Part A is received in formalin and additionally labeled "R10 lymph node" and consists of a single nodular portion of gray-tan anthracotic appearing lymph node having a greatest dimension of 0.8 cm which is submitted entirely in cassette A.

Part B is received in formalin and additionally labeled "R4 lymph node" and consists of three portions of gray-tan nodular soft tissue grossly consistent with lymph node ranging from 0.5 to 0.8 cm submitted in toto in cassette B.

C is received in formalin and additionally labeled "R2 lymph node" and consists of three nodular portions of gray-tan soft tissue grossly consistent with lymph nodes which range from 0.8 to 1.2 cm in greatest dimension. The two lesser nodes are submitted in toto in cassette C1. The larger node is bisected and submitted entirely in cassette C2.

Part D is received in formalin and additionally labeled "Level 7 lymph node" and consists of a single nodular portion of gray-tan soft tissue grossly consistent with lymph node having dimensions of 1.1 x 0.9 x 0.8 cm. This tissue is bisected and submitted entirely in cassette D.

Part E is received fresh for frozen section evaluation having been previously partially incised additionally labeled "right upper lobe diagnosed mass (FSE+X)." The specimen consists of a product of a right upper lobectomy having overall dimensions of 11 x 8 x 4.2 cm. Notable by palpation and confirmed by step-sectioning there is a subpleural mass which has a tan-white partially necrotic cut surface with dimensions of 4 x 3.8 x 3 cm which approaches to within 2 cm of the bronchial margin of surgical resection. A portion of this lesion is submitted for frozen section evaluation (FSE) with residual frozen section tissue submitted in cassette E1. Sectioning through the remaining lung parenchyma reveals probable congestion without distinct "mass." Within the area of the hilum there are no additional lymph nodes grossly identified.

Sections are submitted as follows:

- E1 residual frozen section tissue;
- E2 bronchial and vascular margins of surgical resection;
- E3-6 representative sections of "mass"
- E7 congested uninvolved lung parenchyma.

Part F is received in formalin additionally labeled "Level 8 lymph node" and consists of a single 2 mm gray-tan soft tissue which is submitted in toto in cassette F.

Microscopic Description:

The final diagnosis of each specimen incorporates the microscopic examination findings.

[page 3 of 3]
Taken [REDACTED]

END OF REPORT

Source: NCI Genomic Data Commons file 48b90e12-d291-4e27-8583-ea21defceb14 (TCGA-91-6836.89441C7C-1E09-4B73-8CC3-27CBA26F3BD3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).